Somatic mutation profile of tumor specimen MMRF_2828_1_BM_CD138pos (aliquot MMRF_2828_1_BM_CD138pos_T1_KHS5U_L16555) from MMRF case MMRF_2828, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.4 years (20,218 days).
Specimen MMRF_2828_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97224286-357a-4565-af1f-aa184de9c7fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2828_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2828_1_PB_WBC_C2_KHS5U_L16602; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6464bca0-9bd4-4a19-b118-1550d6aa51e0

The open-access MAF lists 109 somatic variants for this specimen: 50 protein-altering or splice-affecting, 12 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 22, Intron 14, Silent 12, 5'UTR 4, 5'Flank 4, Nonsense Mutation 3, Splice Region 2, Frame Shift Del 2, 3'Flank 2, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 118/162 reads (73%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFP | c.530C>A p.T177K | Missense Mutation (SNP) | VAF 112/224 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs151308004; called by muse, mutect2, varscan2
- AGPAT5 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 69/131 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs1444042111; called by muse, mutect2, varscan2
- AHCY | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV54153201; called by muse, mutect2, varscan2
- C8orf33 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1296789232, COSV58895241; called by muse, mutect2, varscan2
- CCNG2 | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs749212577; called by muse, mutect2, varscan2
- CCT8L2 | c.194G>C p.G65A | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV63461772; called by muse, mutect2, varscan2
- GART | c.597+7A>G | Splice Region (SNP) | VAF 123/238 reads (52%) | catalogued as rs1302731824; called by muse, mutect2, varscan2
- GLIS1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as rs1162457085; called by muse, mutect2, varscan2
- H2AC14 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 104/261 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV60798485; called by muse, mutect2, varscan2
- KCNE4 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 61/66 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1297682048; called by muse, mutect2, varscan2
- KMT2C | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1189358773, COSV51516608; called by muse, mutect2
- MYH9 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768721880; called by muse, mutect2, varscan2
- OPLAH | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369434485; called by muse, mutect2, varscan2
- PLPP3 | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as rs759896266; called by muse, mutect2, varscan2
- QSER1 | c.3718C>G p.Q1240E (on ENST00000399302; = p.Q1369E on NM_001076786.3) | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs562035984; called by muse, mutect2, varscan2
- SHF | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52051253; called by muse, mutect2
- SLBP | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs1454397473; called by muse, mutect2, varscan2
- SLC4A3 | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 47/48 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56096719; called by muse, mutect2, varscan2
- ST6GAL2 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 75/121 reads (62%) | PolyPhen possibly damaging (0.772); catalogued as rs530496847, COSV64530013; called by muse, mutect2, varscan2
- AADACL2 | c.941_944del p.D314Afs*18 | Frame Shift Del (DEL) | VAF 74/220 reads (34%) | called by pindel, varscan2
- ACSL6 | c.839C>G p.T280R (on ENST00000379240; = p.T305R on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARID4B | c.3922T>C p.S1308P | Missense Mutation (SNP) | VAF 19/500 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); called by muse, mutect2
- BIN1 | c.1674G>A p.Q558= (on ENST00000316724 / NM_001320642.1; = p.Q419= on NM_004305.4) | Splice Region (SNP) | VAF 4/89 reads (4%) | called by muse, mutect2
- C8orf76 | c.500G>A p.W167* | Nonsense Mutation (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- CAPRIN2 | c.1282A>G p.K428E | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- CDCA2 | c.2693A>C p.K898T | Missense Mutation (SNP) | VAF 104/209 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CDKN1B | c.535_536dup p.N180Qfs*46 | Frame Shift Ins (INS) | VAF 107/165 reads (65%) | called by mutect2, pindel, varscan2
- DCAF8L1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 86/89 reads (97%) | called by muse, mutect2, varscan2
- ENDOD1 | c.520T>C p.W174R | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIN3B | c.2029C>A p.L677M | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- HNRNPU | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 66/205 reads (32%) | called by muse, mutect2, varscan2
- KCNH6 | c.1241_1248del p.W414Lfs*148 | Frame Shift Del (DEL) | VAF 72/191 reads (38%) | called by mutect2, pindel, varscan2
- LCE1E | c.246C>A p.H82Q | Missense Mutation (SNP) | VAF 58/82 reads (71%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, varscan2
- LHX9 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 49/404 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LIG4 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.197); called by muse, mutect2
- LTB | c.163-2A>G p.X55_splice | Splice Site (SNP) | VAF 159/328 reads (48%) | called by muse, mutect2, varscan2
- MLLT10 | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PCDH15 | c.4496A>G p.D1499G | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); called by muse, mutect2
- PEX11G | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPFIA4 | c.3506A>C p.E1169A (on ENST00000447715; = p.E1170A on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PRDM16 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PRG4 | c.2906C>A p.T969K | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- RPUSD4 | c.356-2A>T p.X119_splice | Splice Site (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- SHF | c.606C>A p.D202E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.432); called by muse, mutect2
- SLC44A5 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 96/233 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- SNAP25 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STK36 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZP2 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.217); called by muse, mutect2
- ZZZ3 | c.1977A>T p.E659D | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CLEC3A | c.177G>A p.K59= (on ENST00000651443; = p.K50= on NM_005752.6) | Silent (SNP) | VAF 64/129 reads (50%) | catalogued as rs76514387; called by muse, mutect2, varscan2
- COQ4 | c.105C>G p.G35= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as COSV55956766; called by muse, mutect2, varscan2
- GRIN3B | c.2049C>A p.P683= | Silent (SNP) | VAF 50/82 reads (61%) | called by muse, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs376111067; called by muse, varscan2
- LGI4 | c.1041C>T p.R347= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as rs779968006; called by muse, mutect2, varscan2
- LRRC53 | c.1471T>C p.L491= | Silent (SNP) | VAF 77/163 reads (47%) | called by muse, mutect2, varscan2
- METTL25 | c.102C>A p.S34= | Silent (SNP) | VAF 159/346 reads (46%) | called by muse, varscan2
- MOCS1 | c.1011C>G p.S337= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as rs775983848; called by muse, mutect2, varscan2
- MYOCD | c.678C>T p.G226= | Silent (SNP) | VAF 83/209 reads (40%) | called by muse, mutect2, varscan2
- NTRK3 | c.711C>A p.P237= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as rs1050636935; called by muse, mutect2, varscan2
- NUFIP1 | c.909T>C p.N303= | Silent (SNP) | VAF 93/106 reads (88%) | catalogued as rs768170454; called by muse, mutect2, varscan2
- UBA1 | c.1356C>T p.D452= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as rs375669736, COSV60115813; ClinVar: likely benign; called by muse, mutect2
- ARFGAP1 | c.*225C>T | 3'UTR (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.*705G>T | 3'UTR (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2, varscan2
- ATRIP | c.-52C>T | 5'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- BMP6 | c.*991G>C | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- BMP6 | c.*1127G>A | 3'UTR (SNP) | VAF 10/33 reads (30%) | catalogued as rs1294480155; called by muse, mutect2, varscan2
- CACNG4 | c.*342G>A | 3'UTR (SNP) | VAF 14/25 reads (56%) | catalogued as rs1330301663; called by muse, mutect2, varscan2
- CARD9 | c.1078-136G>A | Intron (SNP) | VAF 11/281 reads (4%) | called by muse, mutect2
- CD177 | c.*110G>A | 3'UTR (SNP) | VAF 87/187 reads (47%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.-54C>T | 5'UTR (SNP) | VAF 31/85 reads (36%) | called by muse, mutect2, varscan2
- DELEC1 | n.1188A>G | RNA (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- EGR1 | c.-102G>A | 5'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- FAM166A | c.748-139T>C | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- FAM71B | c.*492C>T | 3'UTR (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2, varscan2
- FUBP3 | c.*1225T>C | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- FZD8 | c.*522T>G | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- HAL | c.*499A>C | 3'UTR (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- HRAS | c.450+172G>A | Intron (SNP) | VAF 17/37 reads (46%) | catalogued as rs1226835781; called by muse, mutect2, varscan2
- IGHV3-7 | c.-27A>G | 5'UTR (SNP) | VAF 101/206 reads (49%) | called by muse, varscan2
- IMMP2L | c.239+94432T>A | Intron (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2, varscan2
- ITIH4 | c.760-107G>T | Intron (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- KDM4C | c.435+392T>G | Intron (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- LPXN | c.*292A>C | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- MAP3K19 | c.3222+238C>T | Intron (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851320 A>G | 5'Flank (SNP) | VAF 83/182 reads (46%) | catalogued as rs539209231; called by muse, mutect2, varscan2
- MOCS1 | c.*933G>A | 3'UTR (SNP) | VAF 130/303 reads (43%) | catalogued as COSV99226992; called by muse, mutect2, varscan2
- MRPS21 | c.*371A>T | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- MYH10 | c.*791G>A | 3'UTR (SNP) | VAF 53/115 reads (46%) | catalogued as rs368643682; called by muse, mutect2, varscan2
- MYO9B | c.2220-147T>C | Intron (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- MYOCD | chr17:12766464 C>T | 3'Flank (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- OTUD6B | chr8:91070181 C>T | 5'Flank (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- OTX1 | c.*1217A>G | 3'UTR (SNP) | VAF 72/147 reads (49%) | called by muse, mutect2, varscan2
- PPP1R18 | chr6:30687306 C>G | 5'Flank (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- PPP2R2C | c.*1641T>A | 3'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, varscan2
- PXDN | c.2104+346T>G | Intron (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- RAD1 | chr5:34905514 C>T | 3'Flank (SNP) | VAF 56/99 reads (57%) | called by muse, mutect2, varscan2
- RNASE12 | c.*43C>T | 3'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- RNF150 | c.*1981A>G | 3'UTR (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- SART1 | c.314-56A>C | Intron (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- SCP2 | c.1081+6041A>G | Intron (SNP) | VAF 33/51 reads (65%) | called by muse, mutect2, varscan2
- SELENOS | c.*7+374C>T | Intron (SNP) | VAF 29/135 reads (21%) | called by muse, mutect2, varscan2
- SMG6 | c.3156-11A>T | Intron (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- SPTAN1 | c.5977+15C>G | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- TMEM30A | c.*1193A>C | 3'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2
- TXNDC16 | c.*1674C>T | 3'UTR (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- VGLL3 | c.*5563T>A | 3'UTR (SNP) | VAF 21/42 reads (50%) | catalogued as rs556892409, COSV101264179; called by muse, mutect2, varscan2
- VPS13B | c.*590T>C | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- ZNF252P | chr8:145004666 C>T | 5'Flank (SNP) | VAF 54/112 reads (48%) | called by muse, mutect2, varscan2
